Somatic mutation profile of tumor specimen HCM-SANG-0286-C20-86A (aliquot HCM-SANG-0286-C20-86A-01D-A937-36) from HCMI case HCM-SANG-0286-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0286-C20-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70a5e702-8f93-4a50-8a90-fd7f78c812f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0286-C20-10B (Blood Derived Normal), aliquot HCM-SANG-0286-C20-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb7939d0-19bf-4e0a-a9ac-93a19c6ad4d6

The open-access MAF lists 284 somatic variants for this specimen: 214 protein-altering or splice-affecting, 56 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 56, Frame Shift Del 11, Intron 10, Nonsense Mutation 10, In Frame Del 4, Frame Shift Ins 3, Nonstop Mutation 2, Translation Start Site 2, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 104/319 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 287/412 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 259/290 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TCTN2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as rs187433682, CM123333; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 278/278 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 208/592 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs759547568; called by muse, mutect2, varscan2
- ABCC5 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 23/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751998938, COSV99656497; called by muse, mutect2
- ACAD9 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 248/370 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs770234633; called by muse, mutect2, varscan2
- ACCS | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs370192805; called by muse, mutect2, varscan2
- ADD3 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 283/386 reads (73%) | SIFT tolerated (0.69); PolyPhen benign (0.241); catalogued as COSV53326488; called by muse, mutect2, varscan2
- ANKRD12 | c.3359T>G p.I1120R | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100042124, COSV50849688; called by muse, mutect2, varscan2
- ANKRD18B | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 146/280 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs932101283; called by muse, mutect2, varscan2
- AP2A1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.813); catalogued as rs769598908, COSV58242828, COSV58243026; called by muse, mutect2, varscan2
- APC | c.3544A>T p.K1182* | Nonsense Mutation (SNP) | VAF 75/325 reads (23%) | catalogued as CD021192, COSV57341394; called by muse, mutect2, varscan2
- AQP4 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV67219042; called by muse, mutect2, varscan2
- ARHGEF11 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.263); catalogued as rs368365495, COSV59357082; called by muse, mutect2
- B3GAT1 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 359/470 reads (76%) | catalogued as rs1035380375; called by muse, mutect2, varscan2
- CACNA1H | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1199006718; called by muse, mutect2, varscan2
- CACNA1S | c.4679G>A p.R1560Q | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372436488; called by muse, mutect2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 205/333 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CATSPER1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 205/670 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372082637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP47 | c.2505T>G p.S835R | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.786); catalogued as COSV52883371; called by muse, mutect2
- CHD6 | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 81/570 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498626; called by muse, mutect2, varscan2
- CNKSR3 | c.1494C>G p.D498E | Missense Mutation (SNP) | VAF 370/371 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101401283; called by muse, mutect2, varscan2
- DNAH7 | c.4761C>A p.F1587L | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs1189877737, COSV56770098, COSV56776303; called by muse, mutect2
- EML1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 254/254 reads (100%) | catalogued as COSV99214946; called by muse, mutect2, varscan2
- FAT3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1001662868, COSV53111028; called by muse, mutect2, varscan2
- FAT4 | c.7816G>A p.A2606T | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747229172, COSV58683547; called by muse, mutect2, varscan2
- FHOD3 | c.3035A>G p.K1012R (on ENST00000359247 / NM_001281739.3; = p.K1029R on NM_025135.5) | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.87); catalogued as rs1459567596; called by muse, mutect2
- FRAS1 | c.7084C>T p.R2362* | Nonsense Mutation (SNP) | VAF 177/364 reads (49%) | catalogued as rs777438557; called by muse, mutect2, varscan2
- H2AC15 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 184/627 reads (29%) | catalogued as rs746231334; called by pindel, varscan2
- HECTD3 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 151/279 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1390520764, COSV64670611; called by muse, mutect2, varscan2
- HIVEP1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 117/500 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65099007; called by muse, mutect2, varscan2
- HNRNPCL1 | c.311T>A p.M104K | Missense Mutation (SNP) | VAF 192/280 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs778148450; called by muse, mutect2, varscan2
- IGSF10 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 254/284 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs372539492; called by muse, mutect2, varscan2
- JPH3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 467/469 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759496599; called by muse, mutect2, varscan2
- KANSL1L | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 260/291 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754026837; called by muse, mutect2, varscan2
- KLK1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 195/373 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs768176494; called by muse, mutect2, varscan2
- LRP12 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 185/186 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770729650, COSV52626697; called by muse, mutect2, varscan2
- MUC16 | c.11659A>T p.N3887Y | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs1227647715; called by muse, mutect2
- MUC7 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1316927617; called by muse, mutect2, varscan2
- MYO15A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 418/421 reads (99%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs934249137, COSV52761349; called by muse, mutect2, varscan2
- MYOF | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100826024; called by muse, mutect2, varscan2
- NAPRT | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 32/1168 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1371680357; called by muse, mutect2
- NDN | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as rs993170550, COSV100086154, COSV100086535; called by muse, mutect2
- NDUFS1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181556411, COSV51911186; called by muse, mutect2
- NLRP8 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759131290, COSV52587344; called by muse, mutect2, varscan2
- OR2J1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 583/585 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.582); catalogued as rs777091944, COSV65850450; called by muse, mutect2, varscan2
- OR6Q1 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 137/533 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV56933511; called by muse, mutect2, varscan2
- OTOF | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 228/373 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs200972155; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 398/606 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA9 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 156/638 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs140634296; called by muse, mutect2, varscan2
- PCDHB2 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 136/600 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52032822; called by muse, mutect2, varscan2
- PEX5 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV56955562; called by muse, mutect2, varscan2
- PKD1L1 | c.6668G>A p.R2223H | Missense Mutation (SNP) | VAF 112/526 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs563223320, COSV56977907; called by muse, mutect2, varscan2
- PLD2 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.93); catalogued as rs777822488; called by muse, mutect2, varscan2
- PRKAA2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 197/382 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs370738439, COSV64802734; called by muse, mutect2, varscan2
- PRKCI | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV99855721; called by muse, mutect2, varscan2
- PTCHD4 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 155/425 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV59786302; called by muse, mutect2, varscan2
- RBBP6 | c.53C>G p.T18S | Missense Mutation (SNP) | VAF 132/519 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs938522432; called by muse, mutect2, varscan2
- RBM12 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 104/529 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1250216283, COSV58290944; called by muse, mutect2, varscan2
- RINT1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57560961; called by muse, mutect2, varscan2
- RIPK4 | c.1549C>T p.R517C (on ENST00000352483; = p.R469C on NM_020639.3) | Missense Mutation (SNP) | VAF 390/391 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs771190743; called by muse, mutect2, varscan2
- SLC45A2 | c.454T>C p.F152L | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as rs202120684; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A17 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs767666097; called by muse, mutect2, varscan2
- SLITRK1 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 130/436 reads (30%) | catalogued as rs751727163; called by muse, mutect2, varscan2
- SPEM3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142001182; called by muse, mutect2, varscan2
- SPRR2G | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 236/663 reads (36%) | PolyPhen possibly damaging (0.619); catalogued as COSV64203496; called by muse, mutect2, varscan2
- SRC | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 159/805 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252138081, COSV62441668; called by muse, mutect2, varscan2
- SZT2 | c.7892G>A p.R2631H (on ENST00000634258 / NM_001365999.1; = p.R2574H on NM_015284.4) | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs769989601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANC1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs757915552, COSV55083923; called by muse, mutect2, varscan2
- TENM3 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 325/502 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1324480533, COSV69301962, COSV69311034; called by muse, mutect2, varscan2
- TFDP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64740014; called by muse, mutect2, varscan2
- TLR4 | c.1951G>C p.V651L (on ENST00000355622 / NM_138554.5; = p.V611L on NM_003266.4) | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV100842935, COSV62924327; called by muse, mutect2, varscan2
- TMEM237 | c.961A>T p.I321L (on ENST00000409883 / NM_001044385.3; = p.I313L on NM_152388.4) | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53807523; called by muse, mutect2, varscan2
- TNXB | c.9553G>A p.A3185T (on ENST00000647633; = p.A2938T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/497 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs780721675, COSV64488384; called by muse, mutect2, varscan2
- TRIM71 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1455479185, COSV101070493; called by muse, mutect2, varscan2
- TTN | c.100141G>A p.E33381K (on ENST00000591111; = p.E25957K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/319 reads (10%) | PolyPhen probably damaging (0.994); catalogued as rs727504977, COSV60089185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.58366A>G p.I19456V (on ENST00000591111; = p.I12032V on NM_003319.4) | Missense Mutation (SNP) | VAF 177/359 reads (49%) | PolyPhen benign (0.184); catalogued as COSV60223453; called by muse, mutect2, varscan2
- A2M | c.3682del p.L1228* | Frame Shift Del (DEL) | VAF 118/542 reads (22%) | called by mutect2, pindel, varscan2
- ABAT | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ABCA13 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 132/406 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ACADL | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- ACKR3 | c.1076del p.Q359Rfs*40 | Frame Shift Del (DEL) | VAF 58/196 reads (30%) | called by mutect2, pindel*, varscan2
- ALDH1L1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ALDH4A1 | c.1025A>C p.E342A | Missense Mutation (SNP) | VAF 160/583 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 189/353 reads (54%) | called by mutect2, pindel, varscan2
- AQP4 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARID1A | c.482_490del p.V161_A163del | In Frame Del (DEL) | VAF 191/377 reads (51%) | called by mutect2, pindel, varscan2
- ATP6V1E1 | c.226A>C p.M76L | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- BBOX1 | c.1151A>C p.E384A | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2
- BCL2L15 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 150/293 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- BLVRB | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BMP10 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 163/436 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFC | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- BRWD3 | c.2048T>G p.L683R | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1E | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 109/328 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CAMKV | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CCDC168 | c.6107A>G p.H2036R | Missense Mutation (SNP) | VAF 172/514 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC88B | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- CD8B2 | c.471A>T p.L157F | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH6 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 300/439 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CFAP47 | c.2506G>T p.G836* | Nonsense Mutation (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2, varscan2
- CIP2A | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- COPG1 | c.1086_1091del p.K362_I364delinsN | In Frame Del (DEL) | VAF 69/352 reads (20%) | called by mutect2, pindel, varscan2
- CSMD1 | c.8236G>C p.A2746P (on ENST00000520002; = p.A2745P on NM_033225.6) | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGKB | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHX34 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- DMXL1 | c.4675_4678del p.A1559Ifs*22 | Frame Shift Del (DEL) | VAF 67/282 reads (24%) | called by mutect2, pindel, varscan2
- DOCK7 | c.3689C>G p.S1230C (on ENST00000635253 / NM_001367561.1; = p.S1199C on NM_033407.3) | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.195); called by muse, mutect2
- DPP10 | c.1018del p.A340Lfs*23 | Frame Shift Del (DEL) | VAF 87/370 reads (24%) | called by mutect2, pindel, varscan2
- FBXO38 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 40/594 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- FBXW7 | c.937A>G p.I313V (on ENST00000281708 / NM_001349798.2; = p.I233V on NM_018315.5) | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCHSD1 | c.832A>C p.S278R | Missense Mutation (SNP) | VAF 23/502 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2
- FOXI3 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 148/489 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSD2 | c.2250G>C p.*750Yext*24 | Nonstop Mutation (SNP) | VAF 37/112 reads (33%) | called by mutect2, varscan2
- GAB1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GADD45GIP1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 180/369 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GDF10 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 82/307 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, varscan2
- GDF10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 82/312 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- GPR101 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRP | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 32/367 reads (9%) | called by muse, mutect2
- HDAC3 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIF1AN | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 43/544 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- HPSE2 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 27/609 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.328); called by muse, mutect2
- IGSF6 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 60/627 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2
- IL1RL2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- IRS2 | c.181A>C p.T61P | Missense Mutation (SNP) | VAF 48/842 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.229); called by muse, mutect2
- ITPRID2 | c.720dup p.R241Sfs*4 | Frame Shift Ins (INS) | VAF 14/134 reads (10%) | called by mutect2, varscan2
- KCNC1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- KCNG2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 172/371 reads (46%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KCNH5 | c.726del p.N243Tfs*3 | Frame Shift Del (DEL) | VAF 88/322 reads (27%) | called by mutect2, pindel, varscan2
- KLF13 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 41/410 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2
- KMT2D | c.4016T>A p.L1339Q | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KNDC1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 241/749 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRP1B | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 129/466 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRCC1 | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 295/295 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRN1 | c.24_41del p.I8_V14delinsM | In Frame Del (DEL) | VAF 62/180 reads (34%) | called by mutect2, pindel, varscan2
- LRTM2 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 64/856 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- LYST | c.10418T>C p.V3473A | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MAGI2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 264/441 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MANEAL | c.701T>G p.I234S | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.017); called by muse, mutect2
- MAP9 | c.1006T>A p.S336T | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- MTUS1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MUC12 | c.1756A>T p.S586C (on ENST00000379442; = p.S443C on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/724 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- MUC12 | c.13323A>C p.E4441D (on ENST00000379442; = p.E4298D on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/908 reads (3%) | SIFT deleterious (0.01); called by muse, mutect2
- MYOF | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NAP1L4 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 302/466 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- NDN | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 190/504 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- NEURL1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 99/502 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2
- NLRX1 | c.447_448del p.F150* | Frame Shift Del (DEL) | VAF 172/776 reads (22%) | called by pindel, varscan2
- NMT2 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 190/398 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); called by muse, varscan2
- NMUR2 | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 337/533 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NTSR2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 163/623 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NUAK1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 314/485 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NXNL1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 200/397 reads (50%) | called by muse, mutect2, varscan2
- OAT | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2
- OR8B12 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 128/581 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); called by mutect2, varscan2
- P2RX6 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPN1L | c.95_122del p.A32Gfs*52 | Frame Shift Del (DEL) | VAF 46/583 reads (8%) | called by mutect2, pindel
- PDXK | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLPPR4 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PLXNB3 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 548/550 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.109); called by muse, varscan2
- PODXL2 | c.483A>T p.R161S | Missense Mutation (SNP) | VAF 186/615 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLD2 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 221/692 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKDC | c.7127A>G p.D2376G | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRR9 | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRSS56 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 62/522 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PSPC1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 116/478 reads (24%) | called by muse, mutect2, varscan2
- PYHIN1 | c.1479A>C p.*493Yext*29 | Nonstop Mutation (SNP) | VAF 62/279 reads (22%) | called by muse, mutect2, varscan2
- RAI14 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 177/502 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASA2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASSF1 | c.11_18del p.E4Afs*3 | Frame Shift Del (DEL) | VAF 28/300 reads (9%) | called by mutect2, pindel
- RIMBP2 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 38/600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF130 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 153/253 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF182 | c.664A>G p.S222G | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- RNF213 | c.2813_2819del p.V938Gfs*48 | Frame Shift Del (DEL) | VAF 81/240 reads (34%) | called by mutect2, pindel, varscan2
- SCG3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN8A | c.4325T>A p.I1442N | Missense Mutation (SNP) | VAF 80/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SEC24C | c.2951A>G p.E984G | Missense Mutation (SNP) | VAF 40/639 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINI1 | c.512_513insG p.D171Efs*3 | Frame Shift Ins (INS) | VAF 74/411 reads (18%) | called by mutect2, pindel, varscan2
- SETBP1 | c.1053C>G p.D351E | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SGCG | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC17A7 | c.1435C>G p.H479D | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SLC35F4 | c.1482G>C p.E494D (on ENST00000339762 / NM_001352015.2; = p.E458D on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC49A3 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 227/466 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC4A8 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 277/468 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SMARCA2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SORBS1 | c.2111G>A p.S704N (on ENST00000361941 / NM_001034954.2; = p.S410N on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SPDYA | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 116/372 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPEG | c.8816T>A p.V2939D | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- STOX2 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 155/595 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SYNE1 | c.7916G>T p.W2639L (on ENST00000367255 / NM_182961.4; = p.W2646L on NM_033071.3) | Missense Mutation (SNP) | VAF 152/384 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TCF7L1 | c.345A>C p.K115N | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- TDRD1 | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- THAP10 | c.455A>T p.Q152L | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMEM178B | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 33/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM233 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNKS1BP1 | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 50/795 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2
- TRHDE | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 170/599 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, varscan2
- TRIM24 | c.2573C>A p.T858K (on ENST00000343526 / NM_015905.3; = p.T824K on NM_003852.4) | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIP12 | c.2220A>T p.K740N | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TTLL7 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- UBLCP1 | c.528T>G p.D176E | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.263); called by muse, mutect2
- UHRF1BP1L | c.3204A>C p.E1068D | Missense Mutation (SNP) | VAF 27/470 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- USP34 | c.1106T>G p.L369R | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- USP48 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- XRCC1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFP36L2 | c.551_552dup p.S185Afs*3 | Frame Shift Ins (INS) | VAF 174/605 reads (29%) | called by mutect2, pindel, varscan2
- ZNF266 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.1548_1552delinsT p.H517Ffs*57 | Frame Shift Del (DEL) | VAF 100/307 reads (33%) | called by pindel, varscan2*
- ZNF549 | c.1349G>A p.C450Y (on ENST00000376233 / NM_001199295.2; = p.C437Y on NM_153263.2) | Missense Mutation (SNP) | VAF 161/286 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF565 | c.1382G>A p.C461Y (on ENST00000355114; = p.C421Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 198/402 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF800 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 304/491 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK2 | c.5925C>T p.S1975= | Silent (SNP) | VAF 178/479 reads (37%) | catalogued as rs1443580091; called by muse, mutect2, varscan2
- ART3 | c.378A>G p.R126= | Silent (SNP) | VAF 35/335 reads (10%) | catalogued as COSV100587966; called by muse, mutect2, varscan2
- BCL9 | c.3501A>G p.G1167= | Silent (SNP) | VAF 56/460 reads (12%) | called by muse, mutect2, varscan2
- BMP5 | c.225C>A p.S75= | Silent (SNP) | VAF 134/418 reads (32%) | catalogued as COSV63706774; called by muse, mutect2, varscan2
- CEP120 | c.1887G>A p.P629= | Silent (SNP) | VAF 307/420 reads (73%) | catalogued as rs191422346; called by muse, mutect2, varscan2
- CNNM2 | c.2301G>A p.R767= | Silent (SNP) | VAF 140/413 reads (34%) | called by muse, mutect2, varscan2
- COL6A3 | c.8127G>A p.L2709= | Silent (SNP) | VAF 309/354 reads (87%) | called by muse, mutect2, varscan2
- CPAMD8 | c.45C>T p.P15= | Silent (SNP) | VAF 142/322 reads (44%) | called by muse, mutect2, varscan2
- CTLA4 | c.411G>A p.P137= | Silent (SNP) | VAF 40/319 reads (13%) | catalogued as rs188862082, COSV55592978; ClinVar: likely benign; called by muse, mutect2, varscan2
- DBX1 | c.195G>A p.P65= | Silent (SNP) | VAF 36/662 reads (5%) | catalogued as rs1349282617, COSV99910205; called by muse, mutect2
- DLL1 | c.1950C>T p.D650= | Silent (SNP) | VAF 214/537 reads (40%) | catalogued as rs570176152, COSV64536860; called by muse, mutect2, varscan2
- DPP9 | c.2019C>T p.A673= (on ENST00000598800; = p.A702= on NM_139159.5) | Silent (SNP) | VAF 186/387 reads (48%) | catalogued as rs764225972; called by muse, mutect2, varscan2
- ELP1 | c.696A>G p.S232= | Silent (SNP) | VAF 120/313 reads (38%) | called by muse, mutect2, varscan2
- FAM200B | c.22A>C p.R8= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- FARP1 | c.51G>A p.P17= | Silent (SNP) | VAF 386/558 reads (69%) | catalogued as rs748482677; called by muse, mutect2, varscan2
- FREM2 | c.6786A>G p.E2262= | Silent (SNP) | VAF 20/395 reads (5%) | catalogued as COSV54835207; called by muse, mutect2
- GDPD4 | c.60T>C p.T20= | Silent (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- GFRA4 | c.447G>A p.P149= | Silent (SNP) | VAF 226/1128 reads (20%) | catalogued as rs1265060253; called by muse, mutect2, varscan2
- GRAMD2A | c.784A>C p.R262= | Silent (SNP) | VAF 27/370 reads (7%) | called by muse, mutect2
- HS3ST4 | c.333G>A p.P111= | Silent (SNP) | VAF 222/626 reads (35%) | called by muse, mutect2, varscan2
- HSD17B13 | c.159T>G p.T53= | Silent (SNP) | VAF 34/279 reads (12%) | called by muse, mutect2, varscan2
- IL18R1 | c.1170A>G p.G390= | Silent (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- KIAA0408 | c.489C>T p.A163= | Silent (SNP) | VAF 183/183 reads (100%) | called by muse, mutect2, varscan2
- KRT73 | c.402G>A p.E134= | Silent (SNP) | VAF 305/462 reads (66%) | called by muse, mutect2, varscan2
- LIPE | c.1623C>A p.A541= | Silent (SNP) | VAF 37/347 reads (11%) | called by muse, mutect2, varscan2
- LYST | c.10419G>C p.V3473= | Silent (SNP) | VAF 94/290 reads (32%) | called by muse, mutect2, varscan2
- MAN2B2 | c.2538C>T p.P846= | Silent (SNP) | VAF 188/413 reads (46%) | catalogued as rs750939182, COSV99577384; called by muse, mutect2, varscan2
- MAP1S | c.1407A>T p.R469= | Silent (SNP) | VAF 149/409 reads (36%) | catalogued as rs1379540821; called by muse, mutect2, varscan2
- MAST1 | c.1059G>A p.E353= | Silent (SNP) | VAF 93/211 reads (44%) | called by muse, mutect2, varscan2
- MMP16 | c.1008C>T p.P336= | Silent (SNP) | VAF 556/557 reads (100%) | catalogued as rs761488939, COSV54153288, COSV54174570, COSV54183762; called by muse, mutect2, varscan2
- MUC22 | c.4839C>T p.G1613= | Silent (SNP) | VAF 58/1011 reads (6%) | catalogued as rs977167089, COSV73736246; called by muse, mutect2
- NLRP10 | c.672C>T p.F224= | Silent (SNP) | VAF 194/625 reads (31%) | called by muse, mutect2, varscan2
- NSMCE4A | c.381A>C p.A127= | Silent (SNP) | VAF 103/330 reads (31%) | called by muse, mutect2, varscan2
- PABPC1L2A | c.21C>T p.G7= | Silent (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- PCDHB1 | c.837C>T p.Y279= | Silent (SNP) | VAF 166/518 reads (32%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1779C>T p.D593= | Silent (SNP) | VAF 292/702 reads (42%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.186C>T p.R62= | Silent (SNP) | VAF 36/646 reads (6%) | catalogued as COSV99340524; called by muse, mutect2
- PCLO | c.3000A>G p.T1000= | Silent (SNP) | VAF 165/484 reads (34%) | called by muse, mutect2, varscan2
- PROB1 | c.1836G>A p.A612= | Silent (SNP) | VAF 226/773 reads (29%) | called by muse, mutect2, varscan2
- PTPRT | c.210C>T p.P70= | Silent (SNP) | VAF 70/343 reads (20%) | called by mutect2, varscan2
- RASGRF2 | c.1692C>T p.F564= | Silent (SNP) | VAF 140/465 reads (30%) | called by muse, mutect2, varscan2
- RTKN | c.1314A>G p.K438= (on ENST00000272430 / NM_001015055.2; = p.K425= on NM_033046.2) | Silent (SNP) | VAF 40/562 reads (7%) | called by muse, mutect2
- RUBCN | c.201C>T p.H67= | Silent (SNP) | VAF 419/453 reads (92%) | catalogued as rs367584242; called by muse, mutect2, varscan2
- SCN8A | c.4326C>T p.I1442= | Silent (SNP) | VAF 82/419 reads (20%) | called by muse, mutect2, varscan2
- SF3B4 | c.1203C>T p.L401= | Silent (SNP) | VAF 306/833 reads (37%) | called by muse, mutect2, varscan2
- SLC44A2 | c.717G>A p.L239= | Silent (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- SPTAN1 | c.6717G>A p.G2239= | Silent (SNP) | VAF 20/355 reads (6%) | catalogued as rs1043927896; called by muse, mutect2
- SRPK1 | c.1569A>C p.L523= | Silent (SNP) | VAF 114/399 reads (29%) | called by muse, mutect2, varscan2
- SVOPL | c.60G>A p.G20= | Silent (SNP) | VAF 99/406 reads (24%) | called by muse, mutect2, varscan2
- TBC1D9B | c.433C>A p.R145= | Silent (SNP) | VAF 39/748 reads (5%) | catalogued as COSV62282681; called by muse, mutect2
- TMEM132D | c.2301C>A p.V767= | Silent (SNP) | VAF 36/598 reads (6%) | catalogued as COSV67160377; called by muse, mutect2
- TMEM200C | c.1854C>T p.S618= | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- TWNK | c.1836A>C p.G612= | Silent (SNP) | VAF 42/708 reads (6%) | called by muse, mutect2
- UBQLN3 | c.1929C>T p.G643= | Silent (SNP) | VAF 274/444 reads (62%) | catalogued as rs777657726, COSV61163185; called by muse, mutect2
- ZFPM1 | c.978G>C p.L326= | Silent (SNP) | VAF 140/309 reads (45%) | called by muse, mutect2, varscan2
- ZNF782 | c.1350C>T p.F450= | Silent (SNP) | VAF 153/322 reads (48%) | catalogued as rs766203575, COSV56652619; called by muse, mutect2, varscan2
- CACNB4 | c.148-90322C>A | Intron (SNP) | VAF 249/287 reads (87%) | called by muse, mutect2, varscan2
- CCDC70 | c.-22G>A | 5'UTR (SNP) | VAF 104/367 reads (28%) | catalogued as rs369776694; called by muse, mutect2, varscan2
- DAOA | c.282-64T>C | Intron (SNP) | VAF 21/322 reads (7%) | called by muse, mutect2
- DIRC1 | n.519C>A | RNA (SNP) | VAF 97/298 reads (33%) | called by muse, mutect2, varscan2
- FGG | c.*480G>A | 3'UTR (SNP) | VAF 60/260 reads (23%) | called by muse, mutect2, varscan2
- GABRD | c.1060-90G>A | Intron (SNP) | VAF 274/746 reads (37%) | catalogued as rs752178524; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4195G>T | Intron (SNP) | VAF 110/463 reads (24%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+36698T>C | Intron (SNP) | VAF 134/378 reads (35%) | called by muse, mutect2, varscan2
- KIAA0895 | c.868-1079G>A | Intron (SNP) | VAF 89/368 reads (24%) | called by muse, mutect2, varscan2
- LRGUK | c.1843+8323G>T | Intron (SNP) | VAF 51/402 reads (13%) | called by muse, mutect2, varscan2
- MPI | c.844+21G>A | Intron (SNP) | VAF 24/423 reads (6%) | called by muse, mutect2
- NACA | c.70+3569G>C | Intron (SNP) | VAF 45/721 reads (6%) | called by muse, mutect2
- OPRM1 | c.1165-10657G>T | Intron (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- ZBTB37 | chr1:173867016 del CA | 5'Flank (DEL) | VAF 66/434 reads (15%) | called by pindel, varscan2
